Surgical pathology report (de-identified scan), TCGA case TCGA-GU-A767, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - UT Southwestern Medical Center at Dallas, specimen TCGA-GU-A767-01A (Primary Tumor).

[page 1 of 4]
Results

BIOPSY OR SURGICAL SPECIMEN

Patient Information

Patient Name

MRN

Sex
Male

DOB

Result Information

Status

Final result

Provider Status
Reviewed

Entry Date

Component Results

Component

Surgical Pathology

Lab

Final Diagnosis

A. Right distal ureter, excision:

- Segment of benign ureter
- No carcinoma is seen
- Frozen section diagnosis is confirmed on permanent sections

B. Left distal ureter, excision:

- Segment of benign ureter
- No carcinoma is seen
- Frozen section diagnosis is confirmed on permanent sections

C. Urinary bladder and prostate, radical cystoprostatectomy:

Urinary Bladder

- Invasive high grade urothelial carcinoma with prominent micropapillary features, extensively involving bladder wall and extending into prostatic urethra, in a background of in situ flat and papillary urothelial carcinoma, see note
- Urothelial carcinoma invades muscularis propria and extends into perivesical adipose tissue (pT3)
- Metastatic urothelial carcinoma in three pelvic lymph nodes (see parts D and E)
- Background urothelium with chronic inflammation and biopsy site changes
- Pathologic TNM stage: pT3b N2 MX
- See CAP template below for further details

Prostate:

- High grade prostatic intraepithelial neoplasia (HG-PIN)

CAP Template for Carcinoma of the Urinary Bladder:

Procedure: Radical cystoprostatectomy

Tumor Site: Anterior and posterior bladder walls
Right and left lateral walls
Trigone
Dome

Tumor Size:

C6CF
ICD-O 3
Carcinoma, urothelial 8120/3
path
Carcinoma, urothelial
micropapillary 8131/3
C6CF
Site Bladder NOS C67.9
path
Bladder wall NOS C67.9
JW 8/13/13

Urothelial Malignancy History		

[page 2 of 4]
Greatest dimension: 7.0 cm
Additional dimensions: 6.5 x 1.5 cm

Histologic Type: Urothelial (transitional cell) carcinoma with micropapillary features

Associated Epithelial Lesions: None identified

Histologic Grade:

Urothelial Carcinoma (WHO 2004/ISUP): High-grade

Tumor Configuration: Papillary / micropapillary

Microscopic Tumor Extension: Tumor invades perivesical tissue, macroscopically (extravesical mass)

Margins: Margins uninvolved by invasive carcinoma
Margins uninvolved by carcinoma in situ

Lymph-Vascular Invasion: Present

Pathologic Staging (pTNM):

Primary Tumor (pT): pT3b: Tumor invades perivesical tissue, macroscopically (extravesical mass)

Regional Lymph Nodes (pN): pN2: Multiple regional lymph node metastases in true pelvis

Specify: Number

examined: 6

Specify: Number

involved: 3

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings:
Inflammation, regenerative and biopsy site changes

Ancillary Studies: Blocks C5 and C10 can be used for additional studies, if needed.

The above pathology diagnosis incorporates data elements as outlined in the CAP Cancer Protocols and Checklists which are based on the AJCC/UICC TNM, 7th edition.

D. Left pelvic lymph nodes, lymphadenectomy:
- Metastatic urothelial carcinoma in one of three lymph nodes (1/3)

E. Right pelvic lymph nodes, lymphadenectomy:
- Metastatic urothelial carcinoma in two of three lymph nodes (2/3)

NotePart C: Sections show a large urothelial tumor extensively involving all bladder walls and extending into the prostatic urethra. The tumor extends along prostatic urethral urothelium and shows areas of focal (urethral) lamina propria invasion but no involvement of the prostatic stroma itself. Tumor invades through the bladder muscularis propria into perivesical adipose tissue (pT3).

The tumor shows prominent micropapillary areas with back to back lacunar spaces containing small tumor nests comprising 60% of tumor. Areas of vascular and

[page 3 of 4]
perineural invasion are seen.

Multiple deeper sections are obtained in the evaluation of this case.

Select slides from the case are reviewed with Dr.

Clinical History

Bladder cancer

Cystoprostatectomy with ureteroileal conduct

Source:

A: Right distal ureter for margin

B: Left distal ureter for margin

C: Bladder and prostate

D: Left pelvic lymph node

E: Right pelvic lymph node

Gross Description

Specimen A is received fresh for frozen section labeled with the patient's name and designated "right distal ureter for margin". The specimen consists of a pink-tan segment of ureter 0.2 cm in length, 0.4 cm in diameter.

Section key:

A1 - specimen entirely submitted

Specimen B is received fresh for frozen section labeled with the patient's name and designated "left distal ureter for margin". The specimen consists of a single pink-tan and segment of ureter 0.2 cm in length and 0.5 cm in diameter.

Section key:

B1 specimen entirely submitted

Specimen C

Type of specimen: Urinary bladder, prostate, seminal vesicles, and vas deferens

The patient's name and case number on the specimen container match the accompanying paperwork and cassettes.

Procedure: Radical cystoprostatectomy

Fixative: Received fresh, subsequently placed in formalin (tissue procurement retained a sample of tumor)

Dimensions:

Bladder: superior to inferior 8.0 cm, left to right 7.0 cm, anterior to posterior 4.5 cm, ureter stumps (left 1.0 cm in length, 0.8 cm in diameter; right 1.0 cm in length, 0.7 cm in diameter, prostate (apex to base 3.6 cm, anterior to posterior 3.0 cm, left to right 5.0 cm), left attached seminal vesicle 2.5 x 1.5 x 1.0 cm; right attached seminal vesicle 2.0 x 1.5 x 2.0 cm; left attached vas deferens 4.0 cm in length, 0.3 cm in diameter; right attached vas deferens 4.0 cm in length, 0.3 cm in diameter.

Description of findings:

Tumor: Large fungating, friable, pink-tan micropapillary mass invading the entire bladder, no normal appearing bladder mucosa identified. The bladder mass extends into the prostatic urethra to within 1.5 cm of the urethral margin. The urethral margin is submitted en face. The bladder mass abuts both ureteral orifices. The bladder mass measures 7.0 x 6.5 cm and up to 1.5 cm in thickness. The mass invades the muscularis and into the posterior fat to within 0.5 cm of the peritonealized posterior surface. The mass does not grossly involve the seminal vesicles or vas deferens, or prostate.

Uninvolved mucosa: The entire effacement of normal bladder.

Prostate, seminal vesicles and vasa deferentia: The prostate parenchyma is nodular yellow-tan. The seminal vesicles and vas deferentia are grossly

[page 4 of 4]
unremarkable.

Ink code:

Bladder:

Anterior: blue

Posterior: orange

Prostate:

Left side: blue

Right side: orange

Anterior: green

Lymph nodes: No lymph nodes are grossly identified.

Section key:

C1 urethral margin, submitted en face

C2, C3 longitudinal section of prostatic urethra to prostatic apex, proximal side

C4 left ureteral orifice

C5 right ureteral orifice

C6 left vas deferens margin

C7 right vas deferens margin

C8, C9 posterior wall, deepest invasion of tumor

C10 bladder trigone

C11 bladder, left lateral wall

C12 bladder, right lateral wall

C13 bladder dome

C14 anterior bladder

C15 C18 representative sections from left side of prostate from apex to base

C19 C22 representative sections of right side of prostate from apex to base

Specimen D is received in formalin labeled with the patient's name and designated "left pelvic lymph nodes". The specimen consists of three irregular fragments of fibrofatty tissue 5.0 x 4.5 x 2.0 cm in aggregate. Thorough examination reveals three suspected lymph nodes ranging from 1.0 2.0 cm in greatest dimension. Two of the lymph nodes are red-brown. One of the lymph nodes is firm and off-white.

Section key:

D1 D3 one bisected lymph node per cassette

Specimen E is received in formalin labeled with the patient's name and designated "right pelvic lymph nodes". The specimen consists of three irregular fragments of fibrofatty tissue 6.0 x 4.0 x 2.0 cm in aggregate. Thorough examination reveals three suspected lymph nodes ranging from 1.5 2.0 cm in greatest dimension. One of the lymph nodes has a diffuse off-white appearance. The second lymph node has multiple foci of off-white, firm nodularities.

Section key:

E1 E3 one bisected lymph node per cassette

Microscopic Description

The stain quality is acceptable.

A-E. The microscopic findings are reflected in the diagnoses rendered.

Intraoperative Diagnosis

Time in: Time out:

AFS1, Right distal ureter margin: "Negative for invasive carcinoma, focal atypia"

BFS1, Left distal ureter margin: "Negative for invasive carcinoma, focal atypia"

Reported to Dr.

***Electronically Signed Out By

[Redacted Signature]

[Redacted Signature]

Source: NCI Genomic Data Commons file 1b49e19f-95dc-44cf-aeb4-3dc129060fc7 (TCGA-GU-A767.4D04BC45-D78F-41DB-8E3B-70763300611A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).